Somatic mutation profile of tumor specimen 0DR53C from CCDI case PBCFPT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.9 years (7,268 days).
Specimen 0DR53C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74c4a690-7eb5-40be-82ba-722d976190f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR536 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03f807fb-3671-4879-bd0c-1356667db2fc

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 147/889 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PRAMEF2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 45/498 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs553285373, COSV53574458; called by muse, mutect2
- ZMYM3 | c.3272G>A p.R1091H | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs919923636, COSV100077762; called by muse, mutect2
- FLNA | c.3084dup p.S1029Qfs*9 | Frame Shift Ins (INS) | VAF 34/235 reads (14%) | called by mutect2, varscan2
